Somatic mutation profile of tumor specimen BA2860D (aliquot aq-BA2860D) from BEATAML1.0 case 2413, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Myelodysplastic syndrome, unclassifiable; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.9 years (25,177 days).
Specimen BA2860D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0de76639-e7e7-49c1-a288-5c0f507f9150.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2173D (Solid Tissue Normal), aliquot aq-BA2173D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ac96cc9-2d8f-46b4-947c-94cd88e8581f

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 40/83 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- ATP6V1B1 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as rs782497280, COSV99314343; called by mutect2, varscan2
- GABRQ | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479573905; called by muse, mutect2, varscan2
- KIF21A | c.3346G>A p.V1116I (on ENST00000361418 / NM_001378440.1; = p.V1103I on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/266 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs781481134; called by muse, mutect2, varscan2
- LINGO2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as rs573296877, COSV58062063; called by mutect2, varscan2
- PXDNL | c.3304C>T p.R1102W | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62485418; called by muse, mutect2
- WDR87 | c.2591G>A p.G864E | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.185); catalogued as COSV100382809; called by muse, mutect2, varscan2
- A1CF | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CUX1 | c.1544_1551del p.N515Ifs*49 | Frame Shift Del (DEL) | VAF 34/100 reads (34%) | called by mutect2, pindel, varscan2
- FLVCR1 | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PCDHGA2 | c.2117C>T p.A706V | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ALDH3B2 | c.949C>T p.L317= | Silent (SNP) | VAF 33/101 reads (33%) | called by muse, mutect2, varscan2
- DNAH2 | c.8094G>A p.K2698= | Silent (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- MYPN | c.693G>A p.Q231= | Silent (SNP) | VAF 23/52 reads (44%) | called by muse, mutect2, varscan2
- PCDH11X | c.123C>T p.G41= | Silent (SNP) | VAF 31/181 reads (17%) | catalogued as COSV53456219, COSV53461674; called by muse, mutect2, varscan2
- SLC6A2 | c.168G>A p.R56= | Silent (SNP) | VAF 86/232 reads (37%) | called by muse, mutect2, varscan2
- CEP57 | c.45+3570G>A | Intron (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- MEF2A | c.*3651T>C | 3'UTR (SNP) | VAF 12/31 reads (39%) | called by mutect2, varscan2
